Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A2AD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A2AD-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial carcinoma.
LMP DATE: Not given.
PROCEDURE: Total abdominal hysterectomy and bilateral salpingo-oophorectomy.
SPECIFIC CLINICAL QUESTION: Not given.
OUTSIDE TISSUE DIAGNOSIS: Not given.
PRIOR MALIGNANCY: Not given.
CHEMORADIATION THERAPY: Not given.
OTHER DISEASES: Not given.
CYTOGENETICS TESTING: Not given.

Collection Date:

FINAL DIAGNOSIS:

PART 1: UTERUS WITH BILATERAL ADNEXA (528 GRAMS), TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. HIGH-GRADE, POORLY DIFFERENTIATED ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE (GRADE 3, STAGE 3B).
- B. TUMOR MEASURES 13 CM IN GREATEST DIMENSION.
- C. TUMOR INVOLVES 100% OF ENDOMETRIAL SURFACE, INVADES 100% OF MYOMETRIUM AND EXTENDS INTO POSTERIOR SEROSAL SURFACE.
- D. HIGH-GRADE POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVES ENDOCERVIX, PARACERVICAL AND PARAMETRIAL TISSUE AND EXTENDS INTO MARGINS OF LEFT PARACERVICAL AND PARAMETRIAL TISSUE.
- E. EXTENSIVE LYMPHOVASCULAR INVASION IDENTIFIED.
- F. LEIOMYOMAS UP TO 6.5 CM, PARTIALLY INVOLVED BY HIGH-GRADE POORLY DIFFERENTIATED ADENOCARCINOMA.
- G. RIGHT OVARY, UNREMARKABLE.
- H. RIGHT FALLOPIAN TUBE WITH PARATUBAL CYST.
- I. LEFT OVARY WITH MATURE CYSTIC TERATOMA.
- J. LEFT FALLOPIAN TUBE WITH HIGH-GRADE POORLY DIFFERENTIATED CARCINOMA IN PARATUBAL TISSUE.

PART 2: LEFT ENLARGED PELVIC LYMPH NODES, DISSECTION -

- A. ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- B. LYMPH NODE SHOWS EXTENSIVE GRANULOMATOUS INFLAMMATION.

PART 3: LEFT PELVIC LYMPH NODES, DISSECTION -

- A. SIX LYMPH NODES, NEGATIVE FOR TUMOR (0/6).
- B. LYMPH NODES SHOW EXTENSIVE GRANULOMATOUS INFLAMMATION.

PART 4: LEFT COMMON ILLAC LYMPH NODES, DISSECTION -

- A. THREE LYMPH NODES, NEGATIVE FOR TUMOR (0/3).
- B. LYMPH NODES SHOW EXTENSIVE GRANULOMATOUS INFLAMMATION.

PART 5: LEFT PERIAORTIC LYMPH NODES, DISSECTION -

- A. FOUR LYMPH NODES, NEGATIVE FOR TUMOR (0/4).
- B. LYMPH NODES SHOW EXTENSIVE GRANULOMATOUS INFLAMMATION.

PART 6: LEFT POSTERIOR CUL-DE-SAC TISSUE, EXCISION -

- HIGH-GRADE, POORLY DIFFERENTIATED CARCINOMA

PART 7: RIGHT PERIAORTIC LYMPH NODES, DISSECTION -

- A. FOUR LYMPH NODES, NEGATIVE FOR TUMOR (0/4).
- B. LYMPH NODES SHOW EXTENSIVE GRANULOMATOUS INFLAMMATION.

PART 8: RIGHT PELVIC LYMPH NODES, DISSECTION -

- A. EIGHT LYMPH NODES, NEGATIVE FOR TUMOR (0/8).
- B. LYMPH NODES SHOW EXTENSIVE GRANULOMATOUS INFLAMMATION.

COMMENT:

Pelvic cytology (_____) is positive for malignant cells.
Immunostaining for AE1/AE3 supports the above interpretation of lymph nodes.
Grocott and Acid fast stain is pending and the results will be reported in the addendum.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA: HYSTERECTOMY

TUMOR TYPE:

SPECIMENS
Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Poorly differentiated (FIGO 3)

ARCHITECTURAL GRADE:

Poorly differentiated

NUCLEAR GRADE:

Grade 3

TUMOR SIZE:

Maximum dimension: 130 mm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 100 %, Posterior endomyometrium: 100 %

DEPTH OF INVASION:

Into serosa

STRUCTURES INVOLVED:

Cervical stroma, Adnexa, Uterine serosa

MARGINS OF RESECTION:

Parametrium margin is positive for tumor

ANGIOLYMPHATIC INVASION:

Yes

LYMPH NODES POSITIVE:

Number of lymph nodes positive: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 26

T STAGE, PATHOLOGIC:

pT3b

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

Not applicable

FIGO STAGE:

IIIB

10A-0-3
adenocarcinoma,
endometrioid, NOS
8380/3

Site: Endometrium C54-1

hw
5/24/11

Source: NCI Genomic Data Commons file 96671eb2-cfff-4aec-97f8-065d4ed0e14d (TCGA-BG-A2AD.E3FBF856-C09F-4F3A-975E-A1D07286A0EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).